Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V5, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V5-01A (Primary Tumor).

[page 1 of 3]
• Head & Neck
• Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

1.4 cm right thyroid nodule with FNA positive for papillary carcinoma. Multiple nodules seen on Ultrasound.

Specimens Submitted:

- 1: Jugular node (fs)
- 2: Right paratracheal lymph node(fs)
- 3: Delphian node
- 4: Total thyroidectomy

DIAGNOSIS:

1. "Jugular node"; biopsy:
- Benign fibroadipose tissue, skeletal muscle and nerves

2. "Right paratracheal lymph node"; biopsy:
- Benign fibroadipose tissue

3. "Delphian node"; biopsy:
- Benign fibroadipose tissue

4. Total thyroidectomy:

Part # 4

Tumor Type:

Papillary carcinoma, tall cell variant $\geq 50\%$ tall cell features per TSS / *mu*

Mitotic Activity:

Not identified

ICD-O-3

carcinoma, papillary, tall cell

Tumor Necrosis:

Not identified

8344/3

Other Tumor Features:

Calcification of non-psammoma type
Marked stromal reaction

Site: thyroid, NOS

Tumor Location:

Right lobe

CT3.9 5-2-12
20

Tumor Size:

Greatest diameter is 1.4 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

[page 2 of 3]
Invades: perithyroidal fibroadipose tissue

Surgical Margins:

Positive for tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

Lymph Nodes:

One benign perithyroidal lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

2.

1) The specimen is received fresh for frozen section consultation, labeled "jugular node frozen" and consists of a 1.2 x 1.0 x 0.3 cm soft tissue. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section consultation, labeled "right paratracheal lymph nodes" and consists of two pieces of adipose tissue measuring 0.9 and 1.1 cm in greatest dimension. There is no lymph node identified grossly. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3). The specimen is received in formalin labeled "Delphian node." It consists of a single piece of pale tan soft tissue measuring 0.7 x 0.6 x 0.3 cm. The specimen is entirely submitted.

Summary of sections:

U - undesignated

4). The specimen is received fresh and placed in formalin, labeled "total thyroidectomy, stitch marks right lobe" and consists of a thyroid weighing 11.5 g after fixation. The right lobe measures 4.2 x 2.1 x 1.2 cm, the left lobe measures 4 x 2 x 1 cm and the isthmus measures 1.7 x 0.7 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.4 x 1.2 x 1.1 cm white-tan, irregular, partly calcified tumor nodule in the right lobe. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen submitted for the remaining tissue is serially sectioned and entirely submitted.

[page 3 of 3]
Summary of sections:
N - nodule, right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Jugular node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Right paratracheal lymph node(fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Delphian node

Block	Sect. Site	PCs
1	U	1

Part 4: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
6	LL	6
6	N	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Jugular node (fs): Benign fibromuscular tissue. No lymphoid tissue present.
Permanent Diagnosis: Same
2. Frozen Section Diagnosis: Right paratracheal lymph node (fs): Benign fibrous and fatty tissue.
Permanent Diagnosis: Same

Source: NCI Genomic Data Commons file 0aa91072-8f61-4376-8b38-1c4f9f66cbb7 (TCGA-DJ-A3V5.39961D6B-E822-45F5-A744-E97BDB40AF85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).